Somatic mutation profile of tumor specimen 0E1MC4 from CCDI case PBCWIR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1MC4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72c6ecc9-40f7-4dc7-9abb-c17f4c0d8c2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1MAH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6c28be2-990d-4612-a928-47c531495b59

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, 3'UTR 2, Nonsense Mutation 2, 5'UTR 2, Intron 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.3737-1G>A p.X1246_splice | Splice Site (SNP) | VAF 319/439 reads (73%) | catalogued as COSV64874104; called by muse, mutect2, varscan2
- CACNA1B | c.6272C>T p.P2091L | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746163681, COSV53130003; called by muse, mutect2, varscan2
- KIRREL3 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs867080090; called by muse, mutect2, varscan2
- KLHL6 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 28/602 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429797234, COSV100385102; called by muse, mutect2
- MPO | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56569254; called by muse, mutect2, varscan2
- NEXMIF | c.4130C>G p.S1377C | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV50088033; called by muse, mutect2, varscan2
- PLEKHG5 | c.1393-8C>T | Splice Region (SNP) | VAF 37/89 reads (42%) | catalogued as rs745431460; called by muse, mutect2, varscan2
- SYK | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 96/324 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773659676; called by muse, mutect2, varscan2
- SZT2 | c.5680C>T p.R1894W (on ENST00000634258 / NM_001365999.1; = p.R1837W on NM_015284.4) | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs761963698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.45161G>A p.R15054Q (on ENST00000591111; = p.R7630Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/532 reads (4%) | PolyPhen probably damaging (0.996); catalogued as rs794729451, COSV59870134; ClinVar: uncertain significance; called by muse, mutect2
- ABCC9 | c.2908G>C p.V970L | Missense Mutation (SNP) | VAF 34/1143 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- ASXL2 | c.2728C>G p.P910A | Missense Mutation (SNP) | VAF 234/576 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DSG3 | c.2821G>T p.G941C | Missense Mutation (SNP) | VAF 32/934 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- EPHA7 | c.2050A>T p.S684C | Missense Mutation (SNP) | VAF 90/717 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- FGD2 | c.597T>A p.Y199* | Nonsense Mutation (SNP) | VAF 144/492 reads (29%) | called by mutect2, varscan2
- GK2 | c.1249A>T p.I417F | Missense Mutation (SNP) | VAF 44/824 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.836); called by muse, mutect2
- KMT2E | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 26/886 reads (3%) | called by muse, mutect2
- NCEH1 | c.406C>G p.P136A (on ENST00000538775; = p.P104A on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/884 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.011); called by muse, mutect2
- NF1 | c.5045_5046del p.C1682* (on ENST00000358273 / NM_001042492.3; = p.C1661* on NM_000267.3) | Frame Shift Del (DEL) | VAF 123/643 reads (19%) | called by mutect2, pindel, varscan2
- OR2Y1 | c.829dup p.Y277Lfs*? | Frame Shift Ins (INS) | VAF 192/619 reads (31%) | called by mutect2, pindel, varscan2
- OTOGL | c.5044C>T p.L1682F (on ENST00000547103; = p.L1673F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 220/500 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- POSTN | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 198/560 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SLC5A5 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 135/446 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TEAD2 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2
- TXN | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 308/955 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHUK | c.966G>A p.K322= | Silent (SNP) | VAF 32/674 reads (5%) | called by muse, mutect2
- DCHS1 | c.6111C>T p.F2037= | Silent (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- LYZL2 | c.9C>T p.D3= | Silent (SNP) | VAF 100/401 reads (25%) | catalogued as rs573396753; called by muse, mutect2, varscan2
- TM4SF5 | c.282G>A p.S94= | Silent (SNP) | VAF 83/364 reads (23%) | catalogued as rs368661513; called by muse, mutect2, varscan2
- ANLN | c.-95G>T | 5'UTR (SNP) | VAF 116/331 reads (35%) | catalogued as rs774385405, COSV51711211; called by muse, mutect2, varscan2
- HAL | c.*60G>T | 3'UTR (SNP) | VAF 61/219 reads (28%) | catalogued as COSV99701454; called by muse, mutect2, varscan2
- MMP19 | c.1189-21C>A | Intron (SNP) | VAF 22/656 reads (3%) | called by muse, mutect2
- MOCS1 | c.-4C>T | 5'UTR (SNP) | VAF 48/143 reads (34%) | catalogued as rs1477137933; called by muse, mutect2, varscan2
- SPARC | c.*138del | 3'UTR (DEL) | VAF 69/375 reads (18%) | called by mutect2, pindel, varscan2
- STXBP2 | c.578+47C>T | Intron (SNP) | VAF 30/81 reads (37%) | catalogued as rs767263925; called by muse, mutect2, varscan2
